Somatic mutation profile of tumor specimen ALCH-B067-TTP1-A (aliquot ALCH-B067-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B067, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.1 years (24,522 days).
Specimen ALCH-B067-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ef17678-3b43-4eaa-b28c-0e78ca16594e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B067-NB1-A (Blood Derived Normal), aliquot ALCH-B067-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15f18e10-af86-4777-9275-e4057d19d5b1

The open-access MAF lists 63 somatic variants for this specimen: 37 protein-altering or splice-affecting, 10 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Intron 8, 5'UTR 5, Nonsense Mutation 3, 3'Flank 2, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.711G>A p.M237I | Missense Mutation (SNP) | VAF 20/117 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP5M1 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.643); catalogued as rs1156796744; called by muse, mutect2
- CBFA2T3 | c.1540C>A p.R514S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.823); catalogued as COSV51933331; called by muse, mutect2, varscan2
- FAM90A27P | n.424+1G>T | Splice Site (SNP) | VAF 10/55 reads (18%) | catalogued as rs1301563642; called by muse, varscan2
- OR10H2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as rs750560739; called by muse, mutect2, varscan2
- PTPDC1 | c.622G>C p.A208P (on ENST00000375360 / NM_177995.3; = p.A260P on NM_152422.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754823541; called by mutect2, varscan2
- RIMS2 | c.1771G>T p.G591* (on ENST00000666250 / NM_001348490.2; = p.G399* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/184 reads (14%) | catalogued as COSV51665503; called by muse, mutect2, varscan2
- SAMD9 | c.3554C>T p.S1185L | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV66074598; called by muse, mutect2
- SLC17A3 | c.914T>C p.I305T | Missense Mutation (SNP) | VAF 52/344 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs1415329000; called by muse, mutect2, varscan2
- SPATA31D1 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs376270710; called by muse, mutect2, varscan2
- TTYH2 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138129824; called by muse, mutect2, varscan2
- UNC5C | c.1340C>A p.A447D | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); catalogued as COSV71661243; called by muse, varscan2
- ABCA12 | c.3722C>T p.S1241F (on ENST00000272895 / NM_173076.3; = p.S923F on NM_015657.3) | Missense Mutation (SNP) | VAF 51/400 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.1426C>A p.R476S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAV3 | c.73G>C p.V25L | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CGREF1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGR4 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, varscan2
- FASTKD3 | c.1726G>C p.G576R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- FRMD4B | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2
- FZR1 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- GABRA5 | c.30C>G p.I10M | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GABRQ | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- HERC2 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- HFE | c.911C>T p.T304I | Missense Mutation (SNP) | VAF 69/452 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- KAT6A | c.4401G>C p.Q1467H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- LRRC32 | c.1733dup p.N578Kfs*42 | Frame Shift Ins (INS) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- LYPD2 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- MBD2 | c.463del p.L155Sfs*10 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- MYBPC2 | c.2264T>A p.L755H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- NBAS | c.1534A>G p.I512V | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR3A1 | c.567G>T p.Q189H | Missense Mutation (SNP) | VAF 20/225 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- P4HA3 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM7 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- RBMXL2 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | called by muse, varscan2
- RFC1 | c.314C>G p.T105R | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.11); called by muse, mutect2
- TTN | c.13531T>A p.W4511R (on ENST00000591111; = p.W3584R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/121 reads (10%) | PolyPhen probably damaging (0.999); called by muse, mutect2
- ZP1 | c.1742C>A p.S581Y | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ASTN1 | c.1065C>T p.N355= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as rs61758728; called by muse, mutect2
- COL21A1 | c.2076G>T p.G692= | Silent (SNP) | VAF 21/288 reads (7%) | called by muse, mutect2
- DNMT1 | c.582G>A p.K194= | Silent (SNP) | VAF 20/199 reads (10%) | catalogued as rs1339554487; called by muse, mutect2, varscan2
- EMSY | c.2856G>A p.Q952= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV58263233, COSV58267045; called by muse, mutect2, varscan2
- NRXN2 | c.876C>T p.F292= | Silent (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- SLC17A5 | c.1374C>G p.T458= | Silent (SNP) | VAF 39/256 reads (15%) | called by muse, mutect2, varscan2
- SPATC1 | c.1629G>A p.A543= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs782374904; called by muse, mutect2, varscan2
- TPP2 | c.312A>C p.T104= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- TRPM6 | c.5889T>A p.I1963= | Silent (SNP) | VAF 33/352 reads (9%) | called by muse, mutect2, varscan2
- UBA5 | c.78G>A p.Q26= | Silent (SNP) | VAF 3/47 reads (6%) | catalogued as rs1559985876; called by muse, mutect2
- ADAMTS10 | c.-10C>A | 5'UTR (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- ANXA8 | c.-171G>A | 5'UTR (SNP) | VAF 7/49 reads (14%) | catalogued as rs1332480769; called by muse, mutect2, varscan2
- CCDC32 | c.-25G>A | 5'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- FUT3 | c.-7C>A | 5'UTR (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+1017C>T | Intron (SNP) | VAF 19/120 reads (16%) | catalogued as COSV99490671; called by muse, mutect2, varscan2
- HARS2 | c.108+44C>A | Intron (SNP) | VAF 10/51 reads (20%) | called by muse, mutect2, varscan2
- HSD17B3 | c.672+19G>C | Intron (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- KPNA5 | c.-8C>A | 5'UTR (SNP) | VAF 3/18 reads (17%) | catalogued as rs1434559369; called by muse, varscan2
- MUCL3 | c.947-801G>T | Intron (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- PCDH10 | c.*13G>C | 3'UTR (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- STIMATE | c.160+1370C>T | Intron (SNP) | VAF 27/211 reads (13%) | called by muse, mutect2, varscan2
- THRA | c.1110+29G>C | Intron (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- THRA | c.1110+30C>G | Intron (SNP) | VAF 18/123 reads (15%) | called by muse, mutect2, varscan2
- TSPAN14 | chr10:80520765 C>T | 3'Flank (SNP) | VAF 12/130 reads (9%) | catalogued as rs1458467913; called by muse, mutect2
- TSPAN14 | chr10:80520767 C>T | 3'Flank (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- TSPAN32 | c.627+76G>T | Intron (SNP) | VAF 7/31 reads (23%) | called by muse, varscan2
